Surgical pathology report (de-identified scan), TCGA case TCGA-06-0190, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0190-02A (Recurrent Tumor).

Surgical Pathology Report

Patient Name:
Med: Rec.:
DOB: (Age:)
Client:

Accession #:
Phone Number:
Gender: M
Location:
Taken:
Received:
Reported:

Physician(s):
Phy Location:

CLINICAL HISTORY
Not Given

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: A: Left parietal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, left parietal lobe, tumor resection: Glioblastoma multiforme and radiation effects

ICD-10-3 Recurrence

Glioblastoma, multiforme 9440/3
Site: parietal lobe C11.3

hw
2/12/15

COMMENT

Sections show a recurrent glioblastoma with prominent spindle pattern. Radiation effects with coagulation necrosis and cytopathic change are present.

Electronically Signed Out

Senior Staff Pathologist

INTRA-OPERATIVE CONSULTATION

A. Left parietal tumor, excision biopsy: Glioma, 1 block,

, Senior Staff Pathologist

GROSS DESCRIPTION

Multiple tissue fragments, 0.3 to 0.6 cm, all in A1, A2, A3

Senior Staff Pathologist

ICD-9(s):

239.6 239.6

Billing Fee Code(s):

A:

PA: A: Left parietal tumor, excision biopsy
Taken: Received:

Requested by:

Source: NCI Genomic Data Commons file ee4e9e17-72d4-464c-bc87-a4ac9cb41be8 (TCGA-06-0190.46FE21C6-F2DC-4A8A-8E1E-C278DD5FF009.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).